Somatic mutation profile of tumor specimen 0DHOIV from CCDI case PBBUUW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (401 days).
Specimen 0DHOIV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa49e43-591a-4dd5-9367-e3347b89d436.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/038f24a1-f6a2-4c57-ab36-3be186320536

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPRIN2 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs758007570, COSV99195476; called by muse, varscan2
- GTF3C1 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 129/372 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs990170857; called by muse, varscan2
- INTS5 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as rs563584230; called by muse, varscan2
- COQ8B | c.368-95T>C | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
